Somatic mutation profile of tumor specimen TCGA-EJ-5526-01A (aliquot TCGA-EJ-5526-01A-01D-1576-08) from TCGA case TCGA-EJ-5526, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.3 years (20,558 days).
Specimen TCGA-EJ-5526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 340c8911-9fa4-4d22-ab68-7f5585e92f86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5526-10A (Blood Derived Normal), aliquot TCGA-EJ-5526-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/456659cb-6b46-4c4c-a834-4dccc8ae140b

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Del 3, RNA 2, In Frame Del 1, Splice Region 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACER3 | c.728T>G p.L243R | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV53601724; called by muse, mutect2, varscan2
- BSN | c.8876G>A p.R2959H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748163157, COSV56524463; called by mutect2, varscan2
- CBFA2T3 | c.304+1G>T p.X102_splice | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as COSV51931039, COSV51931813; called by muse, mutect2, varscan2
- EFHB | c.2153C>G p.P718R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV55551753; called by muse, mutect2, varscan2
- LCN2 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs750760535, COSV52981581; called by muse, mutect2, varscan2
- MTHFR | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1393335339, COSV64878791; called by muse, mutect2, varscan2
- PIEZO2 | c.8044G>A p.G2682R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53292621; called by muse, mutect2, varscan2
- PPP4R1 | c.2691C>G p.D897E (on ENST00000400556 / NM_001042388.3; = p.D880E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53283677; called by muse, mutect2, varscan2
- RBPMS2 | c.267C>T p.N89= | Splice Region (SNP) | VAF 31/160 reads (19%) | catalogued as rs750140091, COSV55605413; called by muse, mutect2, varscan2
- RORB | c.959G>A p.R320H (on ENST00000396204 / NM_001365023.1; = p.R309H on NM_006914.4) | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974656, COSV65336747; called by muse, mutect2, varscan2
- RREB1 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745668051, COSV58562650; called by muse, mutect2, varscan2
- SAMSN1 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.309); catalogued as COSV53475375; called by muse, mutect2, varscan2
- SSR3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746911247, COSV54021255; called by muse, mutect2, varscan2
- URGCP | c.565G>T p.A189S (on ENST00000453200 / NM_001077663.3; = p.A180S on NM_017920.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs949858966, COSV56251161, COSV99787094; called by muse, mutect2, varscan2
- USH2A | c.12622G>A p.D4208N | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs529589990, COSV56412301; called by muse, mutect2, varscan2
- XK | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.163); catalogued as COSV66120646; called by muse, mutect2, varscan2
- BTBD6 | c.728_731del p.T243Kfs*10 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- IL6ST | c.1316_1328del p.L439Rfs*8 | Frame Shift Del (DEL) | VAF 57/344 reads (17%) | called by mutect2, pindel, varscan2
- PLIN3 | c.787del p.Q263Rfs*14 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PRRC2A | c.30_32del p.G11del | In Frame Del (DEL) | VAF 39/312 reads (13%) | called by mutect2, pindel, varscan2
- COMP | c.1110G>C p.A370= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as rs780972997, COSV55876055; called by muse, mutect2, varscan2
- FAM47B | c.846T>C p.H282= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV61455978; called by muse, mutect2, varscan2
- JPH2 | c.972C>T p.H324= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs757316297, COSV65902933, COSV65905706; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRTM4 | c.1680C>T p.S560= | Silent (SNP) | VAF 57/238 reads (24%) | catalogued as rs1394053583, COSV101298564, COSV69171174; called by muse, mutect2, varscan2
- MSLNL | c.813G>A p.S271= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs374819779; called by muse, mutect2
- PROX1 | c.1359C>T p.S453= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs763701960, COSV54776832; called by muse, mutect2, varscan2
- KIF16B | c.3498+3232T>G | Intron (SNP) | VAF 49/362 reads (14%) | catalogued as COSV61711395; called by muse, mutect2, varscan2
- NBPF25P | n.2000C>T | RNA (SNP) | VAF 18/240 reads (8%) | called by muse, varscan2
- OSGIN1 | n.1634C>T | RNA (SNP) | VAF 24/92 reads (26%) | catalogued as COSV59422475; called by muse, mutect2, varscan2
